MMRF case MMRF_2181 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b10c1d2c-b468-4658-8a23-5b0945d47e0e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 80.3 years (29,336 days); ISS stage: III; Days to last known disease status: 485 days (1.3 years); Days to last follow up: 485 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 304 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 42 days; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 318 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 2): M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 560 mg/dL; Immunoglobulin G 65.8 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 16.3 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 2.73 mmol/L; Leukocytes 4.9 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 310 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 3.43 mmol/L; Albumin 32 g/L; Total Protein 11.2 g/dL; Glucose 9.68 mmol/L.
- Day 77 (ECOG 2): Hemoglobin 5.46 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 154 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 1.75 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 6 mmol/L.
- Day 161 (ECOG 2): Hemoglobin 6.45 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 179 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 7.1 mmol/L.
- Day 231 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.54 mg/dL; Immunoglobulin G 8.02 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 4.84 mmol/L.
- Day 366 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 160 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 6.27 mmol/L.
- Day 415 (ECOG 0): Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 485 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 7.74 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day -3: Weight: 81 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample MMRF_2181_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2181_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
